Surgical pathology report (de-identified scan), TCGA case TCGA-RY-A83Z, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of California San Francisco, specimen TCGA-RY-A83Z-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] (Age:) Sex: Female
Soc. Sec. #: [REDACTED] Location:
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

A. Brain, "left frontotemporal tumor", biopsy: Anaplastic astrocytoma with gemistocytic features, WHO Grade III.

B. Brain, "left frontotemporal tumor", biopsy: Anaplastic astrocytoma with gemistocytic features, WHO Grade III.

COMMENT:

Sections show a hypercellular glial neoplasm composed of gemistocytic astrocytes and smaller elongate cells with high nuclear to cytoplasmic ratio, and markedly hyperchromatic nuclei. Mitotic figures are easily identified. There is no evidence of necrosis or microvascular proliferation. These features are most consistent with an anaplastic astrocytoma with gemistocytic features, WHO grade III.

Immunohistochemical stains were performed and evaluated at [REDACTED] show that the tumor cells are strongly positive for p53 protein and IDH1 (R132H) mutant protein, the latter of which is generally associated with a genetically more favorable subtype of diffuse glioma. The GFAP stain shows patchy positivity, especially in the gemistocytic cells. Neurofilament stains the entrapped neuropil. The Ki-67 labeling index is 18%.

Fluorescence in situ hybridization studies for EGFR amplification and PTEN deletion will be performed at [REDACTED] and the results will be reported separately.

[REDACTED] has reviewed this case and agrees with the diagnosis.

Intraoperative Diagnosis

FS1 (A) Brain, left frontotemporal tumor, biopsy: Malignant glioma, at least anaplastic astrocytoma. Tissue section and cytologic prep.

Microscopic Description

Sections show a dense infiltrate of large atypical cells with overlapping, pleomorphic and hyperchromatic nuclei, irregular nuclear contours and scant cytoplasm. No necrosis or endothelial cell proliferation is present.

GCSE ICD-O-3
Astrocytoma, grade III 9401/3
path
Astrocytoma, gemistocytic 9401/3
Site: GCSE
Brain, supratentorial
NOS 271.9
path
Brain, overlapping lesion
271.8
QW 10/30/13

[page 2 of 2]
Gross Description

The specimen is received fresh in two parts, each labeled with the patient's name and medical record number.

Part A is labeled "left frontotemporal tumor," and consists of a fragment of unoriented, gelatinous, tan-red soft tissue (1.0 x 0.4 x 0.2 cm). A portion of the specimen is submitted for frozen section diagnosis 1, including a smear preparation. The frozen section remnant is submitted in cassette A1 and the remainder of the specimen is submitted in cassette A2.

Part B, additionally labeled "L frontotemporal tumor (permanent)," consists of one irregularly-shaped, membranous fragment of soft, red tissue (0.8 x 0.7 x 0.1 cm), which is submitted intact in cassette B1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the
They have not been cleared or approved by the U. S. Food and Drug Administration.
The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a -year-old female with a left insular grade III glioma (prior biopsy in outside hospital), who undergoes resection.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the
They have not been cleared or approved by the U. S. Food and Drug Administration.
The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Pathology Resident

Signed: Pathologist

Source: NCI Genomic Data Commons file bbafd7b8-90f0-4874-a070-7ee3cdfce4a6 (TCGA-RY-A83Z.923A22A4-A05E-4B5E-B682-1027A84B9EF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).